Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ADRU, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ADRU-TTP1-A (Primary Tumor).

[page 1 of 24]
Results History

SURGICAL PATHOLOGY (Order [REDACTED])

Result Date [REDACTED] +29

Component Results

Component

Report, pathology

Provider: [REDACTED]

Collected: [REDACTED]

Case #: [REDACTED]

+20

Surgical Pathology Report

* Amended *

FINAL PATHOLOGIC DIAGNOSIS

LUNG, RIGHT UPPER LOBE, LOBECTOMY

- moderate to poorly differentiated adenocarcinoma measuring 6 x 6 x 5 cm.
approaching but not penetrating pleura.
bronchial margin without evidence of tumor. (Frozen section

4)

metastatic carcinoma involving one of one hilar lymph node.

POST OBSTRUCTIVE EDEMA AND CHRONIC INFLAMMATION OF DISTAL

LUNG.

Lymph nodes, biopsy

station 4 R. lower paratracheal (frozen section 1)

- no evidence of tumor.

Station 4 R. lower paratracheal (frozen section 2)

- NO evidence of tumor.

Station 7 subcarinal (frozen section 3)

- metastatic poorly differentiated carcinoma.

Station 4 L.

- no evidence of tumor.

Station 8 paraesophageal

- no evidence of tumor.

Station 10 hilar

- no evidence of tumor.

Station 4 R. lower paratracheal

- no evidence of tumor.

Station 4 R (SUBMITTED FOR PERMANENT SECTION).

- metastatic poorly different carcinoma involving one of multiple lymph nodes.

Station 7 subcarinal number two

- no evidence of tumor.
- small numbers of epithelioid granulomas present, special stains for acid-fast and fungal organisms NEGATIVE.

pleura, biopsy

- mesothelial proliferation and focal chronic inflammation.
- no evidence of tumor.

Mediastinal tumor overlying brachial cephalic vein

- fibroadipose tissue with mesothelial proliferation and acute hemorrhage.

- no evidence of tumor.

Rib, sixth, partial resection thoracotomy

- grossly unremarkable rib fragments (2).

**

[page 2 of 24]
Amendments

Amended:

Reason: correct typographical error

No change in diagnosis is reflected in the typo corrections.

Previous Signout Date: +28

Microscopic Description

The patient's tumor is a moderate to poorly differentiated adenocarcinoma which measured up to 6 cm in breadth and extended from immediately below the pleural to within approximately 0.5-cm of the hilum. The margins of the lobectomy are clear but metastatic carcinoma was identified in the single peri-hilar lymph node. Metastatic carcinoma was also identified in the station 7 lymph nodes, and one of the station 4 R. Lymph nodes. The pleural biopsy and specimen submitted as mediastinal tumor overlying brachial cephalic vein shows no evidence of tumor. The granulomas seen in the nodes are of unknown significance. Special stains for acid fast and fungal organisms are negative, but do not rule out infection. Polarization is negative. Sarcoid can cause such granulomas but usually they are more numerous than in this case.

Clinical History

with right lung carcinoma (adenocarcinoma). Need to stage mediastinum. A. Station 4R lower paratracheal (FS1). B. Station 4R lower paratracheal (FS2). C. Station 7 subcarinal (FS3). D. Right lower lobe adenocarcinoma, please freeze tumor in liquid nitrogen for posterity per - freeze bronchial margin. E. Station 4L. F. Portion of 6th rib. G. Pleural debris. H. Station 8 paraesophageal. I. Station 10 (hilar). J. Station 4R lower paratracheal. K. Mediastinal tumor overlying brachial-cephalic vein. L. Station 4R. M. Station 7 subcarinal.

Intra-operative Consultation

FS1 - STATION 4R LOWER PARATRACHEAL LYMPH NODES - NEGATIVE.

FS2 - STATION 4R LOWER PARATRACHEAL LYMPH NODES #2 - NEGATIVE.

FS3 - STATION 7 SUBCARINAL LYMPH NODES - ATYPICAL CELLS FAVOR HISTIOCYTES AND REACTIVE ENDOTHELIAL CELLS. TUMOR ON BIOPSY WAS WELL-MODERATELY DIFFERENTIATED - NEGATIVE.

STAT DX: FS RUL - BRONCHIAL MUCOSAL MARGIN - NEGATIVE, BUT TUMOR IN PERIBRONCHIAL LYMPH NODE IS POSITIVE AND TUMOR CELLS IN RETROSPECT LOOK LIKE CELLS IN STATION 7 LYMPH NODE THAT I THOUGH COULD BE HISTIOCYTES/ENDOTHELIAL. VERY POORLY DIFFERENTIATED AND NOT WELL-MODERATE. INFORMED.

Gross Description

13

A. Station 4R lower paratracheal (FS1), an approximately 0.5 cm anthracotic lymph node which is bisected, used for frozen section and subsequently embedded (A1).

B. Station 4R (FS2), an approximately 0.8 cm lymph node which is frozen in its entirety and subsequently embedded (B1).

[page 3 of 24]
C. Station 7 (FS3) portions of multiple lymph nodes which are frozen in their entirety and subsequently embedded (C1).

D. Right upper lobe (FS4), a lobectomy specimen measuring 11.5 x 8 x 5.5 cm. The pleura opposite the hilar margin is pale and distorted over an area of approximately 5 x 4.5 cm. The bronchial margin was previously taken for frozen and subsequently embedded in (D1). A full section of the hilar structures immediately distal to the previously submitted margin is taken in (D2). Sections through the lobectomy show the tumor to measure 6 x 6 x 5 cm. It has a gray-tan focally necrotic surface. Sections of the tumor are taken in (D3 and D4), the margins of the tumor and adjacent lung (D5) and distant uninvolved lung (D6).

E. Station 4L, a 0.2 and a 0.4 cm fragment of anthracotic lymph node, all in (E1).

F. Portion of sixth rib, two fragments of grossly unremarkable rib each measuring approximately 1 to 1.2 cm in length. No sections are taken.

G. Pleural debris, an irregular fibrinous to filamentous fragment of grayish material measuring approximately 0.5 cm in aggregate dimension is received with a fragment of blood clot. All in (G1).

H. Station 8 paraesophageal, a single approximately 0.8 cm anthracotic lymph node, all in (H1).

I. Station hilar 10, two fragments of anthracotic lymph node measuring in aggregate 1 x 1 x 0.3 cm. All in (I1).

J. Station 4R lower paratracheal, a single up to 0.6 cm anthracotic lymph node, All in (J1).

K. Mediastinal tumor overlying brachial-cephalic vein, an irregular sheet of hemorrhagic to gray-tan tissue measuring 3 by up to 1.8 by up to 0.3 cm. All in (A1).

L. Station 4R, a mass of lymph nodes and soft tissue measuring 3 x 2.8 by up to 1.0 cm. All in (L1-L4).

M. Station 7 subcarinal, an irregular mass of hemorrhagic tissue, probably lymph node measuring 2.5 x 2 x 0.8 cm. All in (M1 and M2).

+21

Specimen(s) Received

A: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
B: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
C: LYMPH NODE BIOPSY - STATION 7 SUBCARINAL
D: LUNG, LOBECTOMY - RT UPPER LOBE
E: LYMPH NODE BIOPSY - STATION 4L
F: RIB - PORTION OF 6TH RIB*
G: PLEURAL BIOPSY - PLEURA
H: LYMPH NODE BIOPSY - STATION 8 PARAESOPHAGEAL
I: LYMPH NODE BIOPSY - STATION 10 HILAR
J: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
K: MEDIASTINAL MASS RESECTION - MEDIASTINAL TUMOR
L: LYMPH NODE BIOPSY - STATION 4R

[page 4 of 24]
M: LYMPH NODE BIOPSY - STATION 7 SUBCARINAL

Patient Name:

Med. Rec #:

DOB/Age:

Age: 67)

Sex: M

Facility:

Location:

Results

Result Date - +29

Component Results

Component

Report, pathology

Provider:

Collected:

Case #:

Surgical Pathology Report

+20

* Amended *

FINAL PATHOLOGIC DIAGNOSIS

LUNG, RIGHT UPPER LOBE, LOBECTOMY

- moderate to poorly differentiated adenocarcinoma measuring 6 x 6 x 5 cm. approaching but not penetrating pleura. bronchial margin without evidence of tumor. (Frozen section

4)

metastatic carcinoma involving one of one hilar lymph node.

POST OBSTRUCTIVE EDEMA AND CHRONIC INFLAMMATION OF DISTAL

LUNG.

Lymph nodes, biopsy

station 4 R. lower paratracheal (frozen section 1)

- no evidence of tumor.

Station 4 R. lower paratracheal (frozen section 2)

- NO evidence of tumor.

Station 7 subcarinal (frozen section 3)

- metastatic poorly differentiated carcinoma.

Station 4 L.

- no evidence of tumor.

Station 8 paraesophageal

- no evidence of tumor.

Station 10 hilar

- no evidence of tumor.

Station 4 R. lower paratracheal

- no evidence of tumor.

Station 4 R (SUBMITTED FOR PERMANENT SECTION).

- metastatic poorly different carcinoma involving one of multiple lymph nodes.

[page 5 of 24]
Station 7 subcarinal number two

- no evidence of tumor.
- small numbers of epithelioid granulomas present, special stains for acid-fast and fungal organisms NEGATIVE.

pleura, biopsy

- mesothelial proliferation and focal chronic inflammation.
- no evidence of tumor.

Mediastinal tumor overlying brachial cephalic vein

- fibroadipose tissue with mesothelial proliferation and acute hemorrhage.
- no evidence of tumor.

Rib, sixth, partial resection thoracotomy

- grossly unremarkable rib fragments (2).

Amendments

Amended:

Reason: Correct Typographical Error

No change in diagnosis is reflected in teh typo corrections.

Previous Signout Date: +28

Microscopic Description

The patient's tumor is a moderate to poorly differentiated adenocarcinoma which measured up to 6 cm in breadth and extended from immediately below the pleural to within approximately 0.5-cm of the hilum. The margins of the lobectomy are clear but metastatic carcinoma was identified in the single peri-hilar lymph node. Metastatic carcinoma was also identified in the station 7 lymph nodes, and one of the station 4 R. Lymph nodes. The pleural biopsy and specimen submitted as mediastinal tumor overlying brachial cephalic vein shows no evidence of tumor. The granulomas seen in the nodes are of unknown significance. Special stains for acid fast and fungal organisms are negative, but do not rule out infection. Polarization is negative. Sarcoid can cause such granulomas but usually they are more numerous than in this case.

Clinical History

with right lung carcinoma (adenocarcinoma). Need to stage mediastinum. A. Station 4R lower paratracheal (FS1). B. Station 4R lower paratracheal (FS2). C. Station 7 subcarinal (FS3). D. Right lower lobe adenocarcinoma, please freeze tumor in liquid nitrogen for posterity per - freeze bronchial margin. E. Station 4L. F. Portion of 6th rib. G. Pleural debris. H. Station 8 paraesophageal. I. Station 10 (hilar). J. Station 4R lower paratracheal. K. Mediastinal tumor overlying brachial-cephalic vein. L. Station 4R. M. Station 7 subcarinal.

Intra-operative Consultation

FS1 - STATION 4R LOWER PARATRACHEAL LYMPH NODES - NEGATIVE.

FS2 - STATION 4R LOWER PARATRACHEAL LYMPH NODES #2 - NEGATIVE.

FS3 - STATION 7 SUBCARINAL LYMPH NODES - ATYPICAL CELLS FAVOR

[page 6 of 24]
HISTIOCYTES AND REACTIVE ENDOTHELIAL CELLS. TUMOR ON BIOPSY WAS
WELL-MODERATELY DIFFERENTIATED - NEGATIVE. [REDACTED]

STAT DX: FS RUL - BRONCHIAL MUCOSAL MARGIN - NEGATIVE, BUT TUMOR
IN PERIBRONCHIAL LYMPH NODE IS POSITIVE AND TUMOR CELLS IN
RETROSPECT LOOK LIKE CELLS IN STATION 7 LYMPH NODE THAT I THOUGH
COULD BE HISTIOCYTES/ENDOTHELIAL. VERY POORLY DIFFERENTIATED AND
NOT WELL-MODERATE. [REDACTED] INFORMED. [REDACTED]

Gross Description

[REDACTED] 13

- A. Station 4R lower paratracheal (FS1), an approximately 0.5 cm anthracotic lymph node which is bisected, used for frozen section and subsequently embedded (A1).
- B. Station 4R (FS2), an approximately 0.8 cm lymph node which is frozen in its entirety and subsequently embedded (B1).
- C. Station 7 (FS3) portions of multiple lymph nodes which are frozen in their entirety and subsequently embedded (C1).
- D. Right upper lobe (FS4), a lobectomy specimen measuring 11.5 x 8 x 5.5 cm. The pleura opposite the hilar margin is pale and distorted over an area of approximately 5 x 4.5 cm. The bronchial margin was previously taken for frozen and subsequently embedded in (D1). A full section of the hilar structures immediately distal to the previously submitted margin is taken in (D2). Sections through the lobectomy show the tumor to measure 6 x 6 x 5 cm. It has a gray-tan focally necrotic surface. Sections of the tumor are taken in (D3 and D4), the margins of the tumor and adjacent lung (D5) and distant uninvolved lung (D6).
- E. Station 4L, a 0.2 and a 0.4 cm fragment of anthracotic lymph node, all in (E1).
- F. Portion of sixth rib, two fragments of grossly unremarkable rib each measuring approximately 1 to 1.2 cm in length. No sections are taken.
- G. Pleural debris, an irregular fibrinous to filamentous fragment of grayish material measuring approximately 0.5 cm in aggregate dimension is received with a fragment of blood clot. All in (G1).
- H. Station 8 paraesophageal, a single approximately 0.8 cm anthracotic lymph node, all in (H1).
- I. Station hilar 10, two fragments of anthracotic lymph node measuring in aggregate 1 x 1 x 0.3 cm. All in (I1).
- J. Station 4R lower paratracheal, a single up to 0.6 cm anthracotic lymph node, All in (J1).
- K. Mediastinal tumor overlying brachial-cephalic vein, an irregular sheet of hemorrhagic to gray-tan tissue measuring 3 by up to 1.8 by up to 0.3 cm. All in (A1).
- L. Station 4R, a mass of lymph nodes and soft tissue measuring 3 x 2.8 by up to 1.0 cm. All in (L1-L4).

[page 7 of 24]
M. Station 7 subcarinal, an irregular mass of hemorrhagic tissue, probably lymph node measuring 2.5 x 2 x 0.8 cm. All in (M1 and M2).

+21

Specimen(s) Received

A: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
B: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
C: LYMPH NODE BIOPSY - STATION 7 SUBCARINAL
D: LUNG, LOBECTOMY - RT UPPER LOBE
E: LYMPH NODE BIOPSY - STATION 4L
F: RIB - PORTION OF 6TH RIB*
G: PLEURAL BIOPSY - PLEURA
H: LYMPH NODE BIOPSY - STATION 8 PARAESOPHAGEAL
I: LYMPH NODE BIOPSY - STATION 10 HILAR
J: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
K: MEDIASTINAL MASS RESECTION - MEDIASTINAL TUMOR
L: LYMPH NODE BIOPSY - STATION 4R
M: LYMPH NODE BIOPSY - STATION 7 SUBCARINAL

Patient Name:

Med. Rec #:

DOB/Age

(Age: 67)

Sex: M

Facility:

Location:

Results

Result Date

+29

Component Results

Component

Report, pathology

Provider:

Collected:

Case #:

+20

Surgical Pathology Report

* Amended *

FINAL PATHOLOGIC DIAGNOSIS

LUNG, RIGHT UPPER LOBE, LOBECTOMY

- moderate to poorly differentiated adenocarcinoma measuring 6 x 6 x 5 cm. approaching but not penetrating pleura. bronchial margin without evidence of tumor. (Frozen section

4)

metastatic carcinoma involving one of one hilar lymph node.

POST OBSTRUCTIVE EDEMA AND CHRONIC INFLAMMATION OF DISTAL

LUNG.

[page 8 of 24]
[REDACTED]

Lymph nodes, biopsy

station 4 R. lower paratracheal (frozen section 1)

- no evidence of tumor.

Station 4 R. lower paratracheal (frozen section 2)

- NO evidence of tumor.

Station 7 subcarinal (frozen section 3)

- metastatic poorly differentiated carcinoma.

Station 4 L.

- no evidence of tumor.

Station 8 paraesophageal

- no evidence of tumor.

Station 10 hilar

- no evidence of tumor.

Station 4 R. lower paratracheal

- no evidence of tumor.

Station 4 R (SUBMITTED FOR PERMANENT SECTION).

- metastatic poorly different carcinoma involving one of multiple lymph nodes.

Station 7 subcarinal number two

- no evidence of tumor.
- small numbers of epithelioid granulomas present, special stains for acid-fast and fungal organisms NEGATIVE.

pleura, biopsy

- mesothelial proliferation and focal chronic inflammation.
- no evidence of tumor.

Mediastinal tumor overlying brachial cephalic vein

- fibroadipose tissue with mesothelial proliferation and acute hemorrhage.
- no evidence of tumor.

Rib, sixth, partial resection thoracotomy

- grossly unremarkable rib fragments (2).
- [REDACTED]

Amendments

Amended: [REDACTED]

Reason: Correct Typographical Error

No change in diagnosis is reflected in teh typo corrections.

Previous Signout Date: [REDACTED] +28

Microscopic Description

The patient's tumor is a moderate to poorly differentiated adenocarcinoma which measured up to 6 cm in breadth and extended from immediately below the pleural to within approximately 0.5-cm of the hilum. The margins of the lobectomy are clear but metastatic carcinoma was identified in the single peri-hilar lymph node. Metastatic carcinoma was also identified in the station 7 lymph nodes, and one of the station 4 R. Lymph nodes. The pleural biopsy and specimen submitted as mediastinal tumor overlying brachial cephalic vein shows no evidence of tumor. The granulomas seen in the nodes are of unknown significance. Special stains for acid fast and fungal organisms are negative, but do not rule out infection. Polarization is negative. Sarcoid can cause such granulomas but usually they are more numerous than in this case.

[page 9 of 24]
Clinical History

with right lung carcinoma (adenocarcinoma). Need to stage mediastinum. A. Station 4R lower paratracheal (FS1). B. Station 4R lower paratracheal (FS2). C. Station 7 subcarinal (FS3). D. Right lower lobe adenocarcinoma, please freeze tumor in liquid nitrogen for posterity per - freeze bronchial margin. E. Station 4L. F. Portion of 6th rib. G. Pleural debris. H. Station 8 paraesophageal. I. Station 10 (hilar). J. Station 4R lower paratracheal. K. Mediastinal tumor overlying brachial-cephalic vein. L. Station 4R. M. Station 7 subcarinal.

Intra-operative Consultation

FS1 - STATION 4R LOWER PARATRACHEAL LYMPH NODES - NEGATIVE.

FS2 - STATION 4R LOWER PARATRACHEAL LYMPH NODES #2 - NEGATIVE.

FS3 - STATION 7 SUBCARINAL LYMPH NODES - ATYPICAL CELLS FAVOR HISTIOCYTES AND REACTIVE ENDOTHELIAL CELLS. TUMOR ON BIOPSY WAS WELL-MODERATELY DIFFERENTIATED - NEGATIVE.

STAT DX: FS RUL - BRONCHIAL MUCOSAL MARGIN - NEGATIVE, BUT TUMOR IN PERIBRONCHIAL LYMPH NODE IS POSITIVE AND TUMOR CELLS IN RETROSPECT LOOK LIKE CELLS IN STATION 7 LYMPH NODE THAT I THOUGH COULD BE HISTIOCYTES/ENDOTHELIAL. VERY POORLY DIFFERENTIATED AND NOT WELL-MODERATE. INFORMED.

Gross Description

13

A. Station 4R lower paratracheal (FS1), an approximately 0.5 cm anthracotic lymph node which is bisected, used for frozen section and subsequently embedded (A1).

B. Station 4R (FS2), an approximately 0.8 cm lymph node which is frozen in its entirety and subsequently embedded (B1).

C. Station 7 (FS3) portions of multiple lymph nodes which are frozen in their entirety and subsequently embedded (C1).

D. Right upper lobe (FS4), a lobectomy specimen measuring 11.5 x 8 x 5.5 cm. The pleura opposite the hilar margin is pale and distorted over an area of approximately 5 x 4.5 cm. The bronchial margin was previously taken for frozen and subsequently embedded in (D1). A full section of the hilar structures immediately distal to the previously submitted margin is taken in (D2). Sections through the lobectomy show the tumor to measure 6 x 6 x 5 cm. It has a gray-tan focally necrotic surface. Sections of the tumor are taken in (D3 and D4), the margins of the tumor and adjacent lung (D5) and distant uninvolved lung (D6).

E. Station 4L, a 0.2 and a 0.4 cm fragment of anthracotic lymph node, all in (E1).

F. Portion of sixth rib, two fragments of grossly unremarkable rib each measuring approximately 1 to 1.2 cm in length. No sections are taken.

[page 10 of 24]
G. Pleural debris, an irregular fibrinous to filamentous fragment of grayish material measuring approximately 0.5 cm in aggregate dimension is received with a fragment of blood clot. All in (G1).

H. Station 8 paraesophageal, a single approximately 0.8 cm anthracotic lymph node, all in (H1).

I. Station hilar 10, two fragments of anthracotic lymph node measuring in aggregate 1 x 1 x 0.3 cm. All in (I1).

J. Station 4R lower paratracheal, a single up to 0.6 cm anthracotic lymph node, All in (J1).

K. Mediastinal tumor overlying brachial-cephalic vein, an irregular sheet of hemorrhagic to gray-tan tissue measuring 3 by up to 1.8 by up to 0.3 cm. All in (A1).

L. Station 4R, a mass of lymph nodes and soft tissue measuring 3 x 2.8 by up to 1.0 cm. All in (L1-L4).

M. Station 7 subcarinal, an irregular mass of hemorrhagic tissue, probably lymph node measuring 2.5 x 2 x 0.8 cm. All in (M1 and M2).

+21

Specimen(s) Received

A: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
B: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
C: LYMPH NODE BIOPSY - STATION 7 SUBCARINAL
D: LUNG, LOBECTOMY - RT UPPER LOBE
E: LYMPH NODE BIOPSY - STATION 4L
F: RIB - PORTION OF 6TH RIB*
G: PLEURAL BIOPSY - PLEURA
H: LYMPH NODE BIOPSY - STATION 8 PARAESOPHAGEAL
I: LYMPH NODE BIOPSY - STATION 10 HILAR
J: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
K: MEDIASTINAL MASS RESECTION - MEDIASTINAL TUMOR
L: LYMPH NODE BIOPSY - STATION 4R
M: LYMPH NODE BIOPSY - STATION 7 SUBCARINAL

Patient Name:

Med. Rec #: DOB/Age: Age: 67) Sex: M

Facility:

Location:

Results

[page 11 of 24]
Result Date [REDACTED] +28

Component Results

Component

Report, pathology

Provider: [REDACTED]

Collected: [REDACTED]

Case #: [REDACTED]

+20

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

LUNG, RIGHT UPPER LOBE, LOBECTOMY

- moderate to poorly differentiated adenocarcinoma measuring 6 x 6 x 5 cm. approaching but not penetrating pleura. bronchial margin without evidence of tumor. (Frozen section

4)

metastatic carcinoma involving one of one hilar lymph node.

POST OBSTRUCTIVE EDEMA AND CHRONIC INFLAMMATION OF DISTAL

LUNG.

Lymph nodes, biopsy

station 4 R. lower paratracheal (frozen section 1)

- no evidence of tumor.

Station 4 R. lower paratracheal (frozen section 2)

- evidence of tumor.

Station 7 subcarinal (frozen section 3)

- metastatic poorly differentiated carcinoma.

Station 4 L.

- no evidence of tumor.

Station 8 paraesophageal

- no evidence of tumor.

Station 10 hilar

- no evidence of tumor.

Station 4 R. lower paratracheal

- no evidence of tumor.

Station 4 R.

- metastatic poorly different carcinoma involving one of multiple lymph nodes.

Station 7 subcarinal number two

- no evidence of tumor.
- small numbers of epithelioid granulomas present, special stains for acid-fast and fungal organisms NEGATIVE.

pleura, biopsy

- mesothelial proliferation and focal chronic inflammation.
- no evidence of tumor.

Mediastinal tumor overlying brachial cephalic vein

- fibroadipose tissue with mesothelial proliferation and acute hemorrhage.

- no evidence of tumor.

Rib, sixth, partial resection thoracotomy

- grossly unremarkable rib fragments (2).

** [REDACTED]

Microscopic Description

The patient's tumor is a moderate to poorly differentiated adenocarcinoma which measured up to 6 cm in breath and extended

[page 12 of 24]
from immediately below the pleural to within approximately 0.5-cm of the hilum. The margins of the lobectomy the are clear but metastatic carcinoma was identified in the single peri-hilar lymph node. Metastatic carcinoma was also identified in the station 7 lymph nodes, and one of the station 4 R. Lymph nodes. The pleural biopsy and specimen submitted as mediastinal tumor overlying brachial cephalic vein shows no evidence of tumor. The granulomas seen in the nodes are of unknown significance. Special stains for acid fast and fungal organisms are negative, but do not rule out infection. Polarization is negative. Sarcoid can cause such granulomas but usually they are more numerous than in this case.

Clinical History

with right lung carcinoma (adenocarcinoma). Need to state mediastinum. A. Station 4R lower paratracheal (FS1). B. Station 4R lower paratracheal (FS2). C. Station 7 subcarinal (FS3). D. Right lower lobe adenocarcinoma, please freeze tumor in liquid nitrogen for posterity per - freeze bronchial margin. E. Station 4L. F. Portion of 6th rib. G. Pleural debris. H. Station 8 paraesophageal. I. Station 10 (hilar). J. Station 4R lower paratracheal. K. Mediastinal tumor overlying brachial-cephalic vein. L. Station 4R. M. Station 7 subcarinal.

Intra-operative Consultation

FS1 - STATION 4R LOWER PARATRACHEAL LYMPH NODES - NEGATIVE.

FS2 - STATION 4R LOWER PARATRACHEAL LYMPH NODES #2 - NEGATIVE.

FS3 - STATION 7 SUBCARINAL LYMPH NODES - ATYPICAL CELLS FAVOR HISTIOCYTES AND REACTIVE ENDOTHELIAL CELLS. TUMOR ON BIOPSY WAS WELL-MODERATELY DIFFERENTIATED - NEGATIVE.

STAT DX: FS RUL - BRONCHIAL MUCOSAL MARGIN - NEGATIVE, BUT TUMOR IN PERIBRONCHIAL LYMPH NODE IS POSITIVE AND TUMOR CELLS IN RETROSPECT LOOK LIKE CELLS IN STATION 7 LYMPH NODE THAT I THOUGH COULD BE HISTIOCYTES/ENDOTHELIAL. VERY POORLY DIFFERENTIATED AND NOT WELL-MODERATE. INFORMED.

Gross Description

13

- A. Station 4R lower paratracheal (FS1), an approximately 0.5 cm anthracotic lymph node which is bisected, used for frozen section and subsequently embedded (A1).
- B. Station 4R (FS2), an approximately 0.8 cm lymph node which is frozen in its entirety and subsequently embedded (B1).
- C. Station 7 (FS3) portions of multiple lymph nodes which are frozen in their entirety and subsequently embedded (C1).
- D. Right upper lobe (FS4), a lobectomy specimen measuring 11.5 x 8 x 5.5 cm. The pleura opposite the hilar margin is pale and distorted over an area of approximately 5 x 4.5 cm. The bronchial margin was previously taken for frozen and subsequently embedded in (D1). A full section of the hilar structures immediately distal to the previously submitted margin is taken in (D2). Sections through

[page 13 of 24]
the lobectomy show the tumor to measure 6 x 6 x 5 cm. It has a gray-tan focally necrotic surface. Sections of the tumor are taken in (D3 and D4), the margins of the tumor and adjacent lung (D5) and distant uninvolved lung (D6).

E. Station 4L, a 0.2 and a 0.4 cm fragment of anthracotic lymph node, all in (E1).

F. Portion of sixth rib, two fragments of grossly unremarkable rib each measuring approximately 1 to 1.2 cm in length. No sections are taken.

G. Pleural debris, an irregular fibrinous to filamentous fragment of grayish material measuring approximately 0.5 cm in aggregate dimension is received with a fragment of blood clot. All in (G1).

H. Station 8 paraesophageal, a single approximately 0.8 cm anthracotic lymph node, all in (H1).

I. Station hilar 10, two fragments of anthracotic lymph node measuring in aggregate 1 x 1 x 0.3 cm. All in (I1).

J. Station 4R lower paratracheal, a single up to 0.6 cm anthracotic lymph node, All in (J1).

K. Mediastinal tumor overlying brachial-cephalic vein, an irregular sheet of hemorrhagic to gray-tan tissue measuring 3 by up to 1.8 by up to 0.3 cm. All in (A1).

L. Station 4R, a mass of lymph nodes and soft tissue measuring 3 x 2.8 by up to 1.0 cm. All in (L1-L4).

M. Station 7 subcarinal, an irregular mass of hemorrhagic tissue, probably lymph node measuring 2.5 x 2 x 0.8 cm. All in (M1 and M2).

+21

Specimen(s) Received

A: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
B: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
C: LYMPH NODE BIOPSY - STATION 7 SUBCARINAL
D: LUNG, LOBECTOMY - RT UPPER LOBE
E: LYMPH NODE BIOPSY - STATION 4L
F: RIB - PORTION OF 6TH RIB*
G: PLEURAL BIOPSY - PLEURA
H: LYMPH NODE BIOPSY - STATION 8 PARAESOPHAGEAL
I: LYMPH NODE BIOPSY - STATION 10 HILAR
J: LYMPH NODE BIOPSY - STATION 4R LOWER PARATRACHEAL
K: MEDIASTINAL MASS RESECTION - MEDIASTINAL TUMOR
L: LYMPH NODE BIOPSY - STATION 4R
M: LYMPH NODE BIOPSY - STATION 7 SUBCARINAL

Patient Name:

Med. Rec #: DOB/Age: (Age: 67) Sex: M

Facility:

Location:

[page 14 of 24]
Results +163

Scan on [REDACTED] by [REDACTED]
Molecular Pathology Report

Scan on [REDACTED] Summary

+900

Result Date - [REDACTED] +21

Results +163

Scan on [REDACTED] by [REDACTED]
Molecular Pathology Report

Scan on [REDACTED] by [REDACTED] Summary

+900

[page 15 of 24]
Re:

1: LUNG,RUL,LOBECTOMY [REDACTED] 10
UNSTAINED SLIDES) (5 SLIDES RECEIVED [REDACTED]

2: LUNG,LLL,PARAAORTA,NEEDLE
BIOPSY [REDACTED] 6 SLIDES RECEIVED

+48

+46

[REDACTED] Lung, right upper lobe, lobectomy [REDACTED]: Pleomorphic carcinoma with giant cell, spindle cell, squamous cell carcinoma and adenocarcinoma patterns
Lung, left lower lobe, paraaorta, needle biopsy [REDACTED]: Elastotic scar with benign respiratory epithelium; no tumor or granulomas are seen

[REDACTED] with a right lung carcinoma

ADDENDUM

Dear [REDACTED]

This addendum documents the results of our molecular diagnostic testing for EGFR and KRAS mutations. The results were negative for EGFR exon 21 deletion and exon 21 L858R mutation as well as KRAS exon 2 mutation (see molecular diagnostics report [REDACTED])

Our histologic diagnosis remains unchanged.

Thank you for sharing this interesting case with us,

Sincerely yours,

[page 16 of 24]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

M

Location:

Service:

Private Outpatient

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

+43

+63

+71

Specimens Submitted:

1: SUBMITTED 5 UNSTAINED AND 1 STAINED SLIDES, RIGHT UPPER LOBE LUNG(OUTSIDE#

Test Performed:

1. Epidermal Growth Factor Receptor Gene Exon 19 deletion analysis
Epidermal Growth Factor Receptor Gene Exon 21 L858R mutation analysis
2. KRAS Gene Exon 2 mutation analysis (codons 12 and 13)
- DNA quality: good.

PRIMER(S):

1. EGFR-Ex19-FWD1, EGFR-Ex19-REV1
EGFR-Ex21-FWD1, EGFR-Ex21-REV1
2. KRAS-E2-intF, KRAS-E2-extR

DIAGNOSTIC INTERPRETATION:

1. Negative for EGFR exon 19 deletion.
Negative for EGFR exon 21 L858R mutation.

Diagnostic sensitivity: This finding does not exclude the possibility of other EGFR mutations. Other types of EGFR mutations are present in approximately 10-15% of cases with EGFR mutations.

Technical sensitivity: These tests cannot detect an EGFR exon 19 deletion or exon 21 L858R mutation if the proportion of tumor cells in the sample studied is less than 5%.

2. Negative for KRAS exon 2 mutation.

Diagnostic sensitivity: This finding does not exclude the possibility of KRAS mutations outside of codons 12 and 13, but such mutations are present in less than 1% of lung cancers with KRAS mutations.

Technical sensitivity: This assay cannot detect a KRAS exon 2 mutation if the proportion of tumor cells in the sample studied is less than 25%.

LAB NOTES:

1. This result can not be used as sole evidence for or against cancer and has to be interpreted in the context of all available clinical and pathological information.

2. This test was developed and its performance characteristics determined by the [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance is not necessary. This test is used for clinical purposes. Pursuant to the requirements of CLIA '88, our laboratory has

[page 17 of 24]
established the accuracy and precision of this test. This test has been approved by [REDACTED] State as a laboratory specific assay.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 18 of 24]
Patient

Specimen no.

Date of birth

Date received

+890

Sex Male

Date reported

+896

SSN Not Provided

Summary

Gene	Value	Result
EML4-ALK	None	No Translocation

Table 1: Summary of genes, values and results

EML4-ALK Mutation: None (No Translocation)

Mutation	Detected
None	✓
V1	
V2	
V3a/b	
V4	
V5a	
V6	
V7	

Interpretation

EML4-ALK defines a molecular subset of NSCLC with distinct clinical characteristics. Patients who harbor this mutation do not benefit from EGFR TKIs.⁴

⁴Shaw et al. 2009. *J Clin Oncol* 27:4247-53.

Legend 1: EML4-ALK translocations were reported from positive allele-specific PCR with primer/probes specific for the EML4-ALK translocations. The mutation assay can detect as low as 1% mutant alleles in a background of wild-type alleles when using the assay within the validated (Ct) range.

+896

Reported:

[page 19 of 24]
Methodology

The [REDACTED] test measures the RNA expression of ERCC1, EGFR, TS, VEGFR2, EML4-ALK and RRM1 by RT-PCR from a patient's tumor tissue. PCR analysis of DNA from the sample is used to determine KRAS, BRAF and EGFR mutational status.

A hematoxylin and eosin (H&E) stained section of a patient's formalin-fixed paraffin embedded tumor specimen is evaluated by a board certified pathologist for tumor content. Specific areas of the specimen are identified for microdissection of tumor cells from normal cells. Adjacent sections of the tumor are sectioned and stained with nuclear fast red (NFR) for visualization for microdissection. After isolation and lysis of the tumor cells, RNA and DNA are isolated separately from the specimen. The RNA is then reverse-transcribed to cDNA, followed by RT-PCR analysis for gene expression using gene specific primers. The results are reported as a ratio of PCR fluorescent signal of the gene of interest to a constitutively expressed gene, beta actin. The presence of DNA mutations is detected by PCR with primers specific for known mutations in KRAS, BRAF or EGFR. The results are expressed relative to the amount of PCR product of the non-mutated gene in each case.

Intended Use

This test was developed and its performance characteristics determined by [REDACTED], Inc. This test has not been cleared or approved by the U.S. Food and Drug Administration. The laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high-complexity clinical testing. These results are adjunctive to the ordering physician's workup.

+896

Reported: [REDACTED]

[page 20 of 24]
Transcription Result

+4

Type	ID	+3	Date and Time	Author
Procedures				

Procedure Orders:

1. PET W CONCURRENT CT. TUMOR LOCALIZATION, SKULL BASE TO MID THIGH. [REDACTED] ordered by [REDACTED]

Document Text

PET-CT BODY SCAN

** HISTORY **:

67 year old man with large right upper lobe mass and left lower lobe mass on CT

** FINDINGS **:

Radiopharmaceutical: 2-F18-fluoro-2-deoxyglucose 17.6 mCi IV

Procedure:

Approximately one hour after injection of the radiopharmaceutical, a CT scan was obtained from the base of the brain to just below the inguinal region. Please note that this is a relatively low dose, 6-slice, non-contrast CT intended for tissue attenuation correction and gross anatomic localization of F18-FDG-avid abnormalities. It is not intended to be a diagnostic study and will not be read as such. An emission scan was then obtained over the same anatomic area in 6 bed positions, 4 minutes per bed position. Data were corrected for tissue attenuation and reconstructed as a whole body rendering for cinematic display and in the transaxial, sagittal, and coronal planes for slice-by-slice review.

Findings:

The patient's glucose level was determined to be 120 mg/dL. The attenuation-corrected PET images show expected radiotracer activity in the visualized portions of the brain. No cervical, supraclavicular, or axillary adenopathy is identified. The left lung field is clear. A large hypermetabolic pulmonary mass is seen in the right upper lobe extending to the right suprahilar region and is due to known lung cancer. No distinct hilar or mediastinal adenopathy is identified. No focal abnormalities are identified in the liver or spleen. No adrenal lesions are identified. Physiologic excretion of the radiotracer is seen in the kidneys bilaterally and in the bladder. No abnormal lymph nodes are identified in the abdominal, retroperitoneal, pelvic, or inguinal regions. No hypermetabolic osseous abnormalities are identified in the visualized portions of the skeleton. The large right upper lobe pulmonary mass does not appear to erode into adjacent bony structures.

** IMPRESSION **:

1.) A large hypermetabolic pulmonary mass is seen in the right upper lobe extending to the right suprahilar region and is due to known lung cancer. No distinct hilar or mediastinal adenopathy is identified.

2.) The left lower lobe pulmonary mass near the aorta seen on the CT of [REDACTED] is not hypermetabolic suggesting a benign etiology.

[page 21 of 24]
DD:

+4

DT:

+4

[REDACTED]

[page 22 of 24]
Transcription Result

Type	ID	Date and Time	Author
Procedures			

Procedure Orders: +788

1. PET W/ CONCURRENT CT TUMOR LOCALIZATION, SKULL BASE TO MID THIGH
[REDACTED] Inbound [REDACTED] ordered by [REDACTED]

Document Text +785

WHOLE BODY PET/CT SCAN

** HISTORY **:

69 years old male with metastatic lung cancer.

Comparison: [REDACTED] +705

** FINDINGS **:

Technique:

Approximately 1 hour following an intravenous administration of 15 mCi of FDG-18, CT without intravenous administration was performed from the base of skull to mid-thigh, followed by PET imaging over the same region. PET images were attenuation corrected using the CT data. Finger blood glucose level of 110 mg/dl.

Findings:

Evaluation of solid organs and soft tissues are limited or nondiagnostic on the CT portion of the scan, due to a lack of IV contrast.

Head and neck: Evaluation of the brain parenchyma is limited by the high normal physiologic FDG uptake in the gray matter, which limits evaluation for brain metastatic disease. Given the above limitation, there are no focally increased FDG uptake in the base of brain to suggest of a metastatic disease.

Paranasal sinuses and mastoid air cells are clear. No evidence of a cervical lymphadenopathy. The thyroid gland is unremarkable. No evidence of a metastatic disease.

Chest:

Interval resolution of a previously described hypermetabolic mediastinum paratracheal lymph node.

Persistent approximately 2.2 x 1.5 cm left lower lobe paramediastinum subpleural density, with stable mild FDG uptake max SUV 1.9. Level of FDG uptake in this density is just slightly higher or equivalent to the background lung uptake (~SUV 1.6). This density may represent rounded atelectasis and stable since chest CT scan from [REDACTED]. Recommend attention on a follow-up scan to assess for stability, if clinical concern exists. +333

Small 4 to 5-mm subpleural nodule in the left lower lobe, image number 196, does not demonstrate increased FDG uptake. This focus is stable in size compared to the prior study from [REDACTED] +706

Evaluation of the lung parenchyma is limited by the breathing

[page 23 of 24]
motion. No suspicious pulmonary nodules with increase FDG uptake.

No evidence of a mediastinum, hilar, or axillary lymphadenopathy. No evidence of a pleural or pericardial effusion. Surgical clips noted in the mediastinum.

Abdomen and pelvis: Limited evaluations of the liver, gallbladder, kidneys, spleen, pancreas, adrenal glands and visualized portion of the bowels demonstrate no significant increased FDG uptakes or hypermetabolic lesions. No evidence of a retroperitoneum or mesenteric lymphadenopathy. No evidence of a significant free fluid. No evidence of a metastatic disease.

Musculoskeletal: No evidence of an osseous metastatic disease based on increase FDG uptake. A small stable sclerotic focus in the right ischium doesn't demonstrate increased FDG uptake and most likely a benign bone island. Degenerative osteophytes changes in the spine. Diffuse mild FDG uptake in the axial skeleton is most likely due to the postchemotherapy effect on bone marrow.

**** IMPRESSION **:**

Interval resolution of hypermetabolic activity in the previously described paratracheal mediastinum lymph node. This lymph node previously measured 1.2cm but now measures about 5mm in size.

Stable 2.2 x 1.5 cm left lower lobe paramediastinum subpleural density compared to the chest CT scan from [REDACTED]. The level of +333 FDG uptake is approximately equivalent to the background lung uptake. This density most likely represent a rounded atelectasis. If clinical concern exists, recommend attention on a follow-up scan.

Stable 4-5mm subpleural nodule in the left lower lobe (image [REDACTED] compared to the prior PET/CT [REDACTED]). This nodule does not demonstrate increased FDG uptake on the current study. Recommend attention on a follow-up scan to assess for stability. +706

No convincing evidence of a recurrence or metastatic disease based on increased FDG uptake.

[page 24 of 24]
Transcription Result

Type	ID	Date	Author
Procedures			

+2034

Procedure Orders:

1. PET W/CONCURRENT CT TUMOR LOCALIZATION, SKULL BASE TO MID THIGH [REDACTED] ordered by [REDACTED]

Document Text

PET/CT BASE OF SKULL TO MID THIGH [REDACTED]

** HISTORY **:

73 year old male with a history of lung ca on surveillance

** FINDINGS **:

Comparison: [REDACTED] +1702

TECHNIQUE: Radiopharmaceutical, 15.5mCi F-18 deoxy glucose.
Fasting blood glucose: 91mg per deciliter.

Approximately 50 minutes following the intravenous administration of the radiopharmaceutical, the patient was placed into the scanner. 6 bed positions with 4 minute emission images were obtained from the base of the skull to mid thighs. Images were reviewed in the sagittal, coronal, and axial planes. Please note that the CT should be considered not fully diagnostic and is used mainly for attenuation and localization purposes.

FINDINGS:

Head and neck:

Sinuses are clear, no hypermetabolic adenopathy

Chest :

Status post R upper lobectomy. No evidence of recurrence. Hilar and mediastinal nodes normal

Abdomen and pelvis:

Physiologic tracer uptake is noted in the liver, spleen, bowel, adrenals, pancreas, and a visualized urinary excretory system.

MSK:

unremarkable

** IMPRESSION **:

Stable PET/CT without evidence of recurrence.

Source: NCI Genomic Data Commons file abfc8342-39c0-4809-b3b5-4e6bc7c715de (ER0204 ER-ADRU Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).